Somatic mutation profile of tumor specimen TCGA-AC-A23H-01A (aliquot TCGA-AC-A23H-01A-11D-A159-09) from TCGA case TCGA-AC-A23H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AC-A23H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8290d5a9-c674-4804-b2cd-c16ccc810656.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A23H-11A (Solid Tissue Normal), aliquot TCGA-AC-A23H-11A-12D-A17G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f463aa5-6351-4c4d-a382-c2f093a34e09

The open-access MAF lists 5,064 somatic variants for this specimen: 3,810 protein-altering or splice-affecting, 1,159 silent, 95 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,307, Silent 1,159, Nonsense Mutation 380, Splice Site 61, Intron 47, Splice Region 27, RNA 22, Frame Shift Del 15, 3'UTR 14, Translation Start Site 9, Nonstop Mutation 7, 5'UTR 6.

Variants (750 of 5,064; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55452713, COSV55455449; called by muse, mutect2, varscan2
- FOXA1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1204900727, COSV51643222, COSV51643797; called by muse, mutect2, varscan2
- GJB1 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs104894823, CM970662, CM973165, COSV62139497; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as rs864622435, COSV52273467; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs758498695, COSV58128352; ClinVar: likely pathogenic; called by mutect2, varscan2
- RNASEH2A | c.690C>A p.F230L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs79767407, CM074477, COSV55551079; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.2608C>G p.L870V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV68641473; called by muse, mutect2, varscan2
- AARS1 | c.1672-1G>C p.X558_splice | Splice Site (SNP) | VAF 21/104 reads (20%) | catalogued as COSV55745887; called by muse, mutect2, varscan2
- AASDH | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV52703765; called by muse, mutect2, varscan2
- AASS | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.243); catalogued as COSV62788618; called by muse, mutect2, varscan2
- AASS | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as COSV62788623; called by muse, mutect2, varscan2
- ABAT | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51619845; called by muse, mutect2, varscan2
- ABAT | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 41/124 reads (33%) | catalogued as COSV51619857; called by muse, mutect2, varscan2
- ABCA10 | c.2029G>T p.D677Y | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52217632; called by muse, mutect2, varscan2
- ABCA12 | c.2674G>T p.D892Y (on ENST00000272895 / NM_173076.3; = p.D574Y on NM_015657.3) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV55947982; called by muse, mutect2, varscan2
- ABCA13 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs534778852, COSV70025503; called by muse, varscan2
- ABCA13 | c.3666C>A p.F1222L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.409); catalogued as COSV70025509; called by muse, mutect2, varscan2
- ABCA3 | c.3455C>G p.S1152C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100069235, COSV57048836; called by muse, mutect2, varscan2
- ABCA3 | c.3205C>T p.H1069Y | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57048845; called by muse, mutect2, varscan2
- ABCA3 | c.1444C>G p.Q482E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV100068451; called by muse, mutect2, varscan2
- ABCA6 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772884126, COSV52634868; called by muse, mutect2, varscan2
- ABCA7 | c.4259G>A p.G1420E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV99565752; called by muse, mutect2
- ABCA8 | c.4690G>C p.E1564Q | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV52196907, COSV99285709; called by muse, mutect2
- ABCA8 | c.1928-1G>A p.X643_splice | Splice Site (SNP) | VAF 8/59 reads (14%) | catalogued as COSV52193241; called by muse, mutect2, varscan2
- ABCB10 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV60619400; called by muse, varscan2
- ABCB10 | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV60619410; called by muse, varscan2
- ABCB11 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs746784473, COSV55584492; called by muse, mutect2, varscan2
- ABCB6 | c.1538C>G p.S513C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.617); catalogued as COSV54692445, COSV54701054; called by muse, mutect2, varscan2
- ABCC4 | c.3493A>G p.K1165E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as COSV65309279; called by muse, mutect2, varscan2
- ABCC6 | c.1633C>T p.L545= | Splice Region (SNP) | VAF 20/56 reads (36%) | catalogued as COSV52740909; called by muse, mutect2, varscan2
- ABCC8 | c.4308-1G>A p.X1436_splice | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV56845608; called by muse, mutect2, varscan2
- ABCC8 | c.2620G>C p.E874Q | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV56845615; called by muse, mutect2, varscan2
- ABCE1 | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV56846014, COSV56847125; called by muse, mutect2, varscan2
- ABHD12 | c.576G>A p.V192= | Splice Region (SNP) | VAF 16/114 reads (14%) | catalogued as COSV59283508; called by muse, mutect2, varscan2
- ABI2 | c.535C>G p.Q179E (on ENST00000295851 / NM_001375719.1; = p.Q173E on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV53689537; called by muse, mutect2, varscan2
- ABI3BP | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV52526672, COSV52550228; called by muse, mutect2, varscan2
- ABI3BP | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV52526696; called by muse, mutect2, varscan2
- ABL1 | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.25); catalogued as COSV59323824, COSV59330563; called by muse, mutect2, varscan2
- ABR | c.1535C>G p.S512C (on ENST00000302538 / NM_021962.5; = p.S475C on NM_001092.5) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52140973, COSV52143706; called by muse, mutect2, varscan2
- ABRA | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61731833; called by muse, mutect2, varscan2
- AC006059.2 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV59605607; called by muse, mutect2, varscan2
- AC011455.2 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV55498017, COSV55499215; called by muse, mutect2, varscan2
- AC011479.1 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs375904286; called by muse, mutect2, varscan2
- ACADVL | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs794727695, COSV50034513, COSV50038489; ClinVar: uncertain significance; called by muse, varscan2
- ACAN | c.6472G>C p.E2158Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as COSV61355088; called by muse, mutect2, varscan2
- ACBD3 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 97/291 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV64729530; called by muse, mutect2, varscan2
- ACBD5 | c.271T>C p.W91R (on ENST00000375888 / NM_001352568.1; = p.W93R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65517799; called by muse, mutect2, varscan2
- ACCSL | c.1119C>G p.H373Q | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV66579812; called by muse, mutect2, varscan2
- ACE | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV52016045; called by muse, mutect2, varscan2
- ACER3 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 102/200 reads (51%) | catalogued as COSV53596534; called by muse, varscan2
- ACHE | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV53814683; called by muse, mutect2, varscan2
- ACKR3 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56020302; called by muse, mutect2, varscan2
- ACOT4 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs766449430, COSV58335312; called by muse, mutect2, varscan2
- ACOX2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV57147453; called by muse, mutect2, varscan2
- ACSL4 | c.313G>C p.E105Q (on ENST00000340800 / NM_022977.2; = p.E64Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61613037; called by muse, mutect2, varscan2
- ACSL5 | c.665G>C p.R222T (on ENST00000354273; = p.R278T on NM_016234.3) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV61128622; called by muse, mutect2, varscan2
- ACSM2A | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54581747, COSV54582975; called by muse, mutect2, varscan2
- ACSS2 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as COSV53622231; called by muse, varscan2
- ACSS3 | c.1700C>G p.S567C | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54083690, COSV54089075; called by muse, mutect2, varscan2
- ACTB | c.364-1G>T p.X122_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV59316501; called by muse, mutect2, varscan2
- ACTG2 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61827339; called by muse, mutect2, varscan2
- ACTL7B | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV65926807; called by muse, mutect2, varscan2
- ACTN2 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63971441; called by muse, mutect2, varscan2
- ACTN3 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV72207521; called by muse, varscan2
- ACTR3 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV54298007; called by muse, mutect2, varscan2
- ACTRT3 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV57753678; called by muse, mutect2, varscan2
- ACTRT3 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100377317, COSV57753699; called by muse, mutect2, varscan2
- ACVR1B | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as COSV57774618, COSV57775037; called by muse, mutect2, varscan2
- ACYP1 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV53134397; called by muse, mutect2, varscan2
- ADAM12 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64101819; called by muse, mutect2, varscan2
- ADAM12 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV100900485; called by muse, mutect2
- ADAM12 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs200657108, COSV64101988; called by muse, mutect2
- ADAM30 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV101023864; called by muse, varscan2
- ADAMTS10 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV54351559; called by muse, mutect2, varscan2
- ADAMTS12 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61254538; called by muse, mutect2, varscan2
- ADAMTS12 | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.086); catalogued as rs1253306623, COSV61254550; called by muse, mutect2, varscan2
- ADAMTS14 | c.1488C>G p.F496L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV64599360; called by muse, mutect2, varscan2
- ADAMTS17 | c.1854G>T p.K618N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV51472198; called by muse, mutect2, varscan2
- ADAMTS20 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs746492092, COSV67125631; called by muse, mutect2, varscan2
- ADAMTS3 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV54383428; called by muse, mutect2, varscan2
- ADAMTS8 | c.1631G>C p.G544A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57290825; called by muse, mutect2, varscan2
- ADAMTS9 | c.3422C>T p.S1141L | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV55774060; called by muse, mutect2, varscan2
- ADAMTS9 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV55774070; called by muse, mutect2, varscan2
- ADAMTSL3 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV54434692; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV54469215, COSV99718784; called by muse, mutect2
- ADAR | c.2893C>A p.P965T | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425973; called by muse, mutect2
- ADAR | c.2693C>G p.S898C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52711774, COSV52718619; called by muse, mutect2, varscan2
- ADAT1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.913); catalogued as COSV57185083; called by muse, mutect2, varscan2
- ADCK2 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); catalogued as COSV50780671; called by muse, mutect2, varscan2
- ADCK2 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1477987414, COSV50780675; called by muse, mutect2, varscan2
- ADCY1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52029430; called by muse, mutect2, varscan2
- ADCY10 | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.42); catalogued as COSV63238322; called by muse, mutect2, varscan2
- ADCY9 | c.4010G>A p.G1337E | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV53570681; called by muse, mutect2, varscan2
- ADCY9 | c.2831C>G p.S944C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.533); catalogued as COSV53570707, COSV53577035; called by muse, mutect2, varscan2
- ADGRA1 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV101658605; called by muse, mutect2, varscan2
- ADGRA3 | c.2207C>G p.S736C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV51559917; called by muse, mutect2, varscan2
- ADGRB1 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60091218; called by muse, mutect2, varscan2
- ADGRE3 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53728057; called by muse, mutect2, varscan2
- ADGRF2 | c.831C>G p.F277L (on ENST00000296862 / NM_001368115.2; = p.F209L on NM_153839.7) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57286202, COSV57287325; called by muse, mutect2, varscan2
- ADGRF5 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs146250899; called by muse, mutect2, varscan2
- ADGRG2 | c.1870C>T p.Q624* (on ENST00000379869 / NM_001079858.3; = p.Q621* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as COSV61337099; called by muse, mutect2, varscan2
- ADGRG2 | c.1564C>G p.Q522E (on ENST00000379869 / NM_001079858.3; = p.Q519E on NM_005756.4) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV61337109; called by muse, mutect2, varscan2
- ADGRG4 | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54948458; called by muse, mutect2, varscan2
- ADGRG7 | c.2359C>T p.L787F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56293294, COSV99841356; called by muse, mutect2, varscan2
- ADGRL4 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100875945; called by muse, mutect2, varscan2
- ADGRV1 | c.11114C>T p.S3705L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs572181833, COSV67977508, COSV67987800; called by muse, mutect2, varscan2
- ADH1C | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs1228670926, COSV72892947; called by muse, mutect2, varscan2
- ADNP | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62424373; called by muse, mutect2, varscan2
- ADNP2 | c.2899G>T p.E967* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51535936; called by muse, mutect2, varscan2
- ADRM1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53351989, COSV53366612; called by muse, mutect2, varscan2
- AEBP1 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56255019; called by muse, mutect2, varscan2
- AEBP1 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV56255032; called by muse, mutect2, varscan2
- AFAP1L1 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57043650; called by muse, mutect2, varscan2
- AFAP1L2 | c.1727C>G p.S576* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV58412021; called by muse, mutect2, varscan2
- AFDN | c.2944G>C p.E982Q | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); catalogued as COSV60036289; called by muse, varscan2
- AFDN | c.3607G>A p.G1203R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV100653359, COSV60036311; called by muse, mutect2, varscan2
- AFF2 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100650097; called by muse, mutect2
- AFF2 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV53974565, COSV53978297; called by muse, mutect2, varscan2
- AGO1 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV64594622; called by muse, mutect2, varscan2
- AGTPBP1 | c.1431G>A p.M477I (on ENST00000357081 / NM_001330701.2; = p.M437I on NM_015239.2) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV61268076; called by muse, mutect2, varscan2
- AGTR1 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.557); catalogued as COSV62557130, COSV62557404; called by muse, mutect2, varscan2
- AHCTF1 | c.6301G>C p.E2101Q (on ENST00000366508; = p.E2075Q on NM_015446.5) | Missense Mutation (SNP) | VAF 69/482 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV58245329; called by muse, mutect2, varscan2
- AHCTF1 | c.4719G>C p.R1573S (on ENST00000366508; = p.R1547S on NM_015446.5) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.083); catalogued as COSV100403662; called by muse, varscan2
- AHCTF1 | c.3724C>G p.L1242V (on ENST00000366508; = p.L1216V on NM_015446.5) | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as COSV58245341; called by muse, mutect2, varscan2
- AHI1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV55622249; called by muse, mutect2, varscan2
- AHNAK | c.6490G>C p.D2164H | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV99947391; called by muse, mutect2, varscan2
- AHNAK2 | c.11617G>A p.E3873K | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1566901052, COSV100317470; called by muse, mutect2
- AHNAK2 | c.9007G>A p.V3003M | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV60906484; called by muse, mutect2, varscan2
- AIFM2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57158477; called by muse, mutect2, varscan2
- AJAP1 | c.1010C>G p.S337W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV65448582, COSV65452912; called by muse, mutect2, varscan2
- AK7 | c.1492G>C p.D498H | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV50869064; called by muse, mutect2, varscan2
- AK9 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV58136535; called by muse, mutect2, varscan2
- AKAP1 | c.2345C>A p.S782Y | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV100532865, COSV61805443; called by muse, mutect2
- AKAP11 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV50292428; called by muse, mutect2, varscan2
- AKAP11 | c.2377C>A p.H793N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV50292430; called by muse, mutect2, varscan2
- AKAP11 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV50292435; called by muse, mutect2
- AKAP17A | c.953G>C p.R318T | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs748366855, COSV58308001; called by muse, mutect2, varscan2
- AKAP9 | c.5935C>T p.R1979C (on ENST00000359028; = p.R1947C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62337737; called by muse, mutect2, varscan2
- AKAP9 | c.11689G>A p.D3897N (on ENST00000359028; = p.D3873N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745335257, COSV50150880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKNA | c.3218G>A p.R1073Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779892625, COSV56334661; called by muse, mutect2, varscan2
- AKNAD1 | c.2282C>G p.S761* | Nonsense Mutation (SNP) | VAF 30/163 reads (18%) | catalogued as COSV64170991; called by muse, mutect2, varscan2
- AKNAD1 | c.1460C>G p.S487* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV62194428; called by muse, mutect2, varscan2
- AKNAD1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV62194448, COSV62197412; called by muse, mutect2, varscan2
- AL441992.2 | c.1282C>G p.Q428E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1031856039, COSV56912110; called by muse, mutect2, varscan2
- ALAS1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV59626650; called by muse, mutect2, varscan2
- ALAS2 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV58187898; called by muse, mutect2, varscan2
- ALAS2 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58187941; called by muse, mutect2, varscan2
- ALDH18A1 | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002848, COSV64661990; called by muse, mutect2, varscan2
- ALDH1A3 | c.539G>A p.W180* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV60900672; called by muse, mutect2, varscan2
- ALDH1L1 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV56410089; called by muse, mutect2, varscan2
- ALG10B | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58142093; called by muse, mutect2, varscan2
- ALG5 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs542695178, COSV53504228; called by muse, mutect2, varscan2
- ALK | c.3626G>C p.R1209P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747643140, COSV101201977, COSV66557012; called by muse, mutect2
- ALKBH5 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV67686700; called by muse, mutect2, varscan2
- ALKBH7 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99831740; called by muse, mutect2
- ALMS1 | c.5954C>T p.S1985F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV52501430; called by muse, mutect2, varscan2
- ALOX12 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs775449597, COSV52348346; called by muse, mutect2, varscan2
- ALOXE3 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs1379299934, COSV59073645; called by muse, mutect2, varscan2
- ALPK2 | c.4946C>T p.S1649L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64489795; called by muse, mutect2, varscan2
- ALPK3 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1282252754, COSV51928483; called by muse, mutect2, varscan2
- ALPK3 | c.3553G>C p.E1185Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV51928524; called by muse, mutect2, varscan2
- AMBP | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV54322196; called by muse, mutect2, varscan2
- AMIGO2 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV56973136, COSV56973624; called by muse, mutect2, varscan2
- AMPD3 | c.1172C>G p.S391C (on ENST00000396553 / NM_001025389.2; = p.S400C on NM_000480.3) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs772445349, COSV67329752; called by muse, mutect2, varscan2
- AMPH | c.1764G>T p.Q588H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV100342055, COSV100343880; called by muse, mutect2
- AMY2A | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 21/134 reads (16%) | catalogued as COSV101340620, COSV70214212; called by mutect2, varscan2
- AMZ2 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV63082417; called by muse, mutect2, varscan2
- ANAPC1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61973979; called by muse, mutect2, varscan2
- ANAPC1 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as COSV61973983; called by muse, mutect2, varscan2
- ANAPC11 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV100485744, COSV58668141; called by muse, mutect2, varscan2
- ANGPTL3 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.608); catalogued as COSV51994554; called by muse, mutect2, varscan2
- ANK2 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002399, COSV52143804; called by muse, mutect2, varscan2
- ANK2 | c.7868C>A p.S2623Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated, low confidence (0.83); PolyPhen possibly damaging (0.66); catalogued as COSV100000403, COSV52143824; called by muse, mutect2, varscan2
- ANKEF1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1408317251, COSV65691898; called by muse, mutect2, varscan2
- ANKFN1 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as COSV59439783; called by muse, mutect2, varscan2
- ANKFN1 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV59439798; called by muse, mutect2, varscan2
- ANKIB1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as COSV56058174; called by muse, varscan2
- ANKMY2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV61010873, COSV61011952; called by muse, mutect2, varscan2
- ANKRD1 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV65467067; called by muse, mutect2, varscan2
- ANKRD11 | c.5149G>A p.E1717K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1376928647, COSV56353630; called by muse, mutect2, varscan2
- ANKRD11 | c.4737G>A p.M1579I | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV56353646; called by muse, mutect2, varscan2
- ANKRD11 | c.3856G>T p.E1286* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV56353665; called by muse, mutect2, varscan2
- ANKRD11 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99969266; called by muse, mutect2
- ANKRD16 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | catalogued as COSV51946562; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100628541; called by muse, mutect2
- ANKRD24 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV53667344; called by muse, mutect2, varscan2
- ANKRD26 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs1264607735, COSV65792491; called by muse, mutect2, varscan2
- ANKRD28 | c.981G>C p.Q327H | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV67516718; called by muse, varscan2
- ANKRD28 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV67516723; called by muse, mutect2, varscan2
- ANKRD28 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs759982054, COSV67516727; called by muse, mutect2, varscan2
- ANKRD44 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV56548564; called by muse, mutect2, varscan2
- ANKRD46 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.971); catalogued as COSV59513345; called by muse, mutect2, varscan2
- ANKS1A | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769495288, COSV64458517; called by muse, mutect2, varscan2
- ANKZF1 | c.1049-1G>A p.X350_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV55475156; called by muse, mutect2, varscan2
- ANO2 | c.48C>A p.S16R (on ENST00000356134 / NM_001278597.3; = p.S20R on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.372); catalogued as COSV59006108; called by muse, mutect2, varscan2
- ANO6 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1162870892, COSV57656086; called by muse, mutect2, varscan2
- ANXA4 | c.10-2A>T p.X4_splice | Splice Site (SNP) | VAF 20/95 reads (21%) | catalogued as COSV101268797; called by muse, mutect2
- AOPEP | c.1138C>G p.H380D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52914066; called by muse, mutect2, varscan2
- AP1G1 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs1251249106, COSV55484634; called by muse, mutect2, varscan2
- AP3B2 | c.3166G>C p.D1056H (on ENST00000261722; = p.D1050H on NM_004644.5) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV55606012; called by muse, mutect2, varscan2
- AP4B1 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV56723041; called by muse, mutect2, varscan2
- AP4S1 | c.296G>C p.S99T | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53554123; called by muse, mutect2, varscan2
- APAF1 | c.1966C>T p.H656Y (on ENST00000551964 / NM_181861.2; = p.H645Y on NM_001160.3) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311834024, COSV59661210, COSV99044691; called by muse, mutect2, varscan2
- APC | c.5176G>C p.E1726Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1561598222, COSV57320816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.8449G>C p.D2817H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57320833; called by muse, mutect2, varscan2
- APEX1 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV51656840; called by muse, mutect2, varscan2
- APEX2 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV58187887; called by muse, mutect2, varscan2
- APLF | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV58142167; called by muse, mutect2, varscan2
- APLP1 | c.483G>C p.Q161H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV52874001; called by muse, mutect2, varscan2
- APOB | c.9739C>G p.Q3247E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV51921524, COSV51924376; called by muse, mutect2, varscan2
- APOB | c.4000G>C p.E1334Q | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV51921530; called by muse, mutect2, varscan2
- APOBR | c.2077G>C p.E693Q (on ENST00000431282; = p.E702Q on NM_018690.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV60488404; called by mutect2, varscan2
- APOH | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV52771137; called by muse, mutect2, varscan2
- APP | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as COSV60992919; called by muse, mutect2, varscan2
- AQP10 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205949010, COSV61474335; called by muse, mutect2, varscan2
- AQP6 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs759606356, COSV100210164; called by muse, mutect2
- ARAP1 | c.3456G>C p.E1152D (on ENST00000393609 / NM_001040118.2; = p.E907D on NM_015242.4) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100501751, COSV61989149; called by muse, mutect2, varscan2
- ARFGEF1 | c.3227G>C p.R1076T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV51601795, COSV51615475; called by muse, mutect2, varscan2
- ARFGEF2 | c.4378G>T p.E1460* | Nonsense Mutation (SNP) | VAF 22/161 reads (14%) | catalogued as COSV64210112, COSV64215456, COSV64216604; called by muse, mutect2, varscan2
- ARFGEF3 | c.2898G>A p.V966= | Splice Region (SNP) | VAF 9/45 reads (20%) | catalogued as COSV52449247; called by muse, mutect2, varscan2
- ARHGAP17 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV51504525; called by muse, mutect2, varscan2
- ARHGAP18 | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63763210; called by muse, mutect2, varscan2
- ARHGAP20 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV52805950; called by muse, mutect2, varscan2
- ARHGAP20 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.171); catalogued as COSV52805971; called by muse, mutect2, varscan2
- ARHGAP28 | c.2032C>T p.H678Y (on ENST00000383472 / NM_001366230.1; = p.H519Y on NM_001010000.3) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58644718, COSV58652115; called by muse, mutect2, varscan2
- ARHGAP29 | c.2611C>G p.Q871E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53107661; called by muse, mutect2, varscan2
- ARHGAP9 | c.1213-1G>A p.X405_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV57357416; called by muse, mutect2, varscan2
- ARHGEF1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61526039; called by muse, mutect2, varscan2
- ARHGEF11 | c.3618G>C p.E1206D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as COSV59352186; called by muse, varscan2
- ARHGEF15 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV62724190; called by muse, mutect2, varscan2
- ARHGEF15 | c.2031G>C p.K677N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62724194; called by muse, mutect2, varscan2
- ARHGEF15 | c.2210G>C p.G737A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.219); catalogued as COSV62724199, COSV62725233; called by muse, mutect2, varscan2
- ARHGEF26 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100726552; called by muse, mutect2
- ARHGEF28 | c.4330C>T p.Q1444* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as rs992967829, COSV55246409; called by muse, mutect2, varscan2
- ARHGEF3 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV56322722; called by muse, mutect2, varscan2
- ARHGEF4 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100388081; called by muse, mutect2
- ARHGEF40 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.775); catalogued as rs1430629156, COSV53877969; called by muse, varscan2
- ARHGEF5 | c.3595C>T p.H1199Y | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50207585; called by mutect2, varscan2
- ARHGEF9 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV53633895; called by muse, mutect2, varscan2
- ARID1A | c.3819G>A p.M1273I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV61370554; called by muse, mutect2, varscan2
- ARID2 | c.1113G>C p.K371N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV57594580; called by muse, mutect2, varscan2
- ARID3A | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.108); catalogued as COSV55042982; called by muse, mutect2, varscan2
- ARID3A | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55042992; called by muse, mutect2, varscan2
- ARL14EP | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56342092, COSV56343111; called by muse, mutect2, varscan2
- ARMC5 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV51654509; called by muse, mutect2, varscan2
- ARMC5 | c.1080C>G p.I360M | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV51654527; called by muse, mutect2, varscan2
- ARMCX1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV65704832; called by muse, mutect2, varscan2
- ARMH3 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV60750290; called by muse, mutect2, varscan2
- ARMT1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV66178314; called by muse, mutect2, varscan2
- ARPC5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV54170755; called by muse, mutect2, varscan2
- ARPP21 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51791271, COSV51794362; called by muse, mutect2, varscan2
- ARSL | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV66964723; called by muse, mutect2, varscan2
- ARVCF | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV54264468; called by muse, mutect2, varscan2
- AS3MT | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as COSV54915379; called by muse, mutect2, varscan2
- ASAP1 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV63043873; called by muse, mutect2, varscan2
- ASAP1 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63043883; called by muse, mutect2, varscan2
- ASB2 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV60110116; called by muse, mutect2, varscan2
- ASH1L | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV64204965, COSV99054583; called by muse, mutect2, varscan2
- ASIC1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV57315864; called by muse, mutect2, varscan2
- ASIC3 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV52501790; called by muse, mutect2, varscan2
- ASIC3 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs750380438, COSV52501799; called by muse, mutect2, varscan2
- ASNS | c.1474C>A p.Q492K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV51550015; called by muse, mutect2, varscan2
- ASPA | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 35/132 reads (27%) | catalogued as COSV52151332; called by muse, mutect2, varscan2
- ASPM | c.9061C>G p.H3021D | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.316); catalogued as COSV54123779; called by muse, mutect2, varscan2
- ASPM | c.8791G>C p.E2931Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1382088362, COSV54123786; called by muse, mutect2, varscan2
- ASPM | c.2942C>A p.T981N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV54123796, COSV99659493; called by muse, mutect2, varscan2
- ASPM | c.2757C>G p.F919L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV54123804; called by muse, mutect2, varscan2
- ASTN1 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs757364439, COSV56060535; called by muse, mutect2, varscan2
- ASTN2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.989); catalogued as COSV57747426; called by muse, mutect2, varscan2
- ATAD2 | c.2833C>G p.P945A | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV54876748; called by muse, mutect2, varscan2
- ATAD2 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | catalogued as COSV54876761, COSV54886733; called by muse, mutect2, varscan2
- ATAD5 | c.4674G>C p.L1558F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV58971638; called by muse, mutect2, varscan2
- ATF2 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV51367762; called by muse, mutect2, varscan2
- ATF6 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV63405745; called by muse, mutect2, varscan2
- ATG12 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57242564; called by muse, mutect2, varscan2
- ATG2A | c.2981G>A p.R994Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs748773349, COSV65965633; called by muse, mutect2, varscan2
- ATG2A | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 18/146 reads (12%) | catalogued as COSV65965638; called by muse, mutect2, varscan2
- ATG3 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1475866495, COSV51925696; called by muse, mutect2, varscan2
- ATG7 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV61610841; called by muse, mutect2, varscan2
- ATL2 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV60050106, COSV60053325; called by muse, mutect2, varscan2
- ATN1 | c.3186C>G p.H1062Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV57546353; called by muse, mutect2, varscan2
- ATP10A | c.2835G>C p.K945N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV63512830; called by muse, mutect2, varscan2
- ATP10D | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56703211, COSV56707021; called by muse, mutect2, varscan2
- ATP11A | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs1375337970, COSV52105235; called by muse, mutect2, varscan2
- ATP1A1 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as COSV55189312; called by muse, mutect2, varscan2
- ATP1A4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247991114, COSV63625335; called by muse, mutect2, varscan2
- ATP2B4 | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV58173888; called by muse, mutect2, varscan2
- ATP2B4 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); catalogued as COSV58173908, COSV58175522; called by muse, mutect2, varscan2
- ATP2B4 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV58173924; called by muse, mutect2, varscan2
- ATP2C1 | c.2605C>T p.Q869* | Nonsense Mutation (SNP) | VAF 36/144 reads (25%) | catalogued as COSV100146681; called by muse, varscan2
- ATP2C2 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52292338; called by muse, mutect2, varscan2
- ATP2C2 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52292354; called by muse, mutect2, varscan2
- ATP4A | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs764421480, COSV52865125; called by muse, mutect2, varscan2
- ATP4A | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs775448586, COSV52865136; called by muse, mutect2, varscan2
- ATP6V1A | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56360724; called by muse, mutect2, varscan2
- ATP6V1C1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67777159, COSV67778305; called by muse, mutect2, varscan2
- ATP7B | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540935874, CM980174, COSV54434734; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATP8A1 | c.525-1G>C p.X175_splice | Splice Site (SNP) | VAF 27/124 reads (22%) | catalogued as COSV52527463; called by muse, mutect2, varscan2
- ATR | c.2246C>G p.S749C | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs906919629, COSV63383294; called by muse, mutect2, varscan2
- ATRIP | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV57175833; called by muse, mutect2, varscan2
- ATRIP | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56496045; called by mutect2, varscan2
- ATRN | c.4015G>C p.E1339Q | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53523138; called by muse, mutect2, varscan2
- ATRX | c.3739G>C p.D1247H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV64870547; called by muse, mutect2, varscan2
- ATRX | c.3270G>C p.E1090D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as rs781992894, COSV100970745; called by muse, varscan2
- ATRX | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.98); catalogued as COSV64870557, COSV64879606; called by muse, varscan2
- ATXN1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as rs201023487; called by muse, mutect2, varscan2
- ATXN2 | c.2878C>T p.Q960* (on ENST00000550104; = p.Q800* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 31/214 reads (14%) | catalogued as COSV66480917; called by muse, mutect2, varscan2
- ATXN2 | c.1024G>C p.D342H (on ENST00000550104; = p.D182H on NM_002973.4) | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66480921; called by muse, mutect2, varscan2
- ATXN2L | c.2737C>G p.L913V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs1331012655, COSV57364626; called by muse, mutect2, varscan2
- AURKA | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV53857647, COSV53860519; called by muse, mutect2, varscan2
- AUTS2 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV61381153; called by muse, mutect2, varscan2
- AVL9 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV59463673; called by muse, mutect2, varscan2
- AXIN2 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs367697282, COSV61055147; called by muse, mutect2, varscan2
- B3GNT5 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58475229, COSV58475801; called by muse, mutect2, varscan2
- B4GALNT2 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV100302561; called by muse, varscan2
- B4GALNT2 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as rs781272860, COSV55924406; called by muse, varscan2
- B4GALNT2 | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV55924416; called by muse, mutect2, varscan2
- B4GALNT3 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV56749297; called by muse, mutect2, varscan2
- B4GALNT4 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.553); catalogued as rs781688656, COSV57321324; called by muse, mutect2, varscan2
- BAAT | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.589); catalogued as rs267602055, COSV52286883; called by muse, varscan2
- BAD | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1484041309, COSV54185477; called by muse, mutect2, varscan2
- BAG2 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs759501055, COSV58097145; called by muse, mutect2, varscan2
- BAG5 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.971); catalogued as COSV54570031, COSV54570391; called by muse, mutect2, varscan2
- BAHD1 | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV60378316; called by muse, mutect2, varscan2
- BAIAP3 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV50103478; called by mutect2, varscan2
- BAX | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.561); catalogued as COSV53168818; called by muse, mutect2, varscan2
- BAZ2A | c.4906G>A p.E1636K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV51630573, COSV99467173; called by muse, mutect2, varscan2
- BAZ2B | c.6001G>A p.E2001K | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as COSV58595072; called by muse, mutect2, varscan2
- BAZ2B | c.5827G>A p.E1943K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58595079; called by muse, mutect2, varscan2
- BAZ2B | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs771370768, COSV58595087; called by muse, mutect2, varscan2
- BAZ2B | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV58595093; called by muse, mutect2, varscan2
- BBS7 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52653998; called by muse, mutect2, varscan2
- BCAN | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61255231; called by muse, mutect2, varscan2
- BCAR3 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV53071297; called by muse, mutect2, varscan2
- BCAS1 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 65/395 reads (16%) | catalogued as COSV65083430; called by muse, mutect2, varscan2
- BCDIN3D | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV61702185; called by muse, mutect2, varscan2
- BCHE | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV52252966; called by muse, mutect2, varscan2
- BCL2L1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56966084; called by muse, mutect2, varscan2
- BCL2L13 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58224666; called by muse, mutect2, varscan2
- BCL2L13 | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100456267, COSV100456268; called by muse, mutect2, varscan2
- BCL9 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV52340321; called by muse, mutect2, varscan2
- BCLAF1 | c.2255C>A p.S752* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV50356715; called by muse, mutect2, varscan2
- BCS1L | c.1142C>G p.A381G | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV55305692; called by muse, mutect2, varscan2
- BEND2 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 74/375 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759938608, COSV66214944; called by muse, mutect2, varscan2
- BEND7 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.973); catalogued as rs141298792; called by muse, mutect2, varscan2
- BEST3 | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56993688; called by muse, mutect2, varscan2
- BHLHE41 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV54378137; called by muse, mutect2, varscan2
- BHMT | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376343021; called by muse, mutect2, varscan2
- BICD1 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99862397; called by muse, mutect2, varscan2
- BICRAL | c.2794C>T p.Q932* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV58403269; called by muse, mutect2, varscan2
- BIN1 | c.908C>G p.S303C (on ENST00000316724 / NM_001320642.1; = p.S287C on NM_004305.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV52115479; called by muse, mutect2, varscan2
- BIRC2 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 61/305 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57160510; called by muse, mutect2, varscan2
- BIRC6 | c.12614C>T p.S4205L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV70194960; called by muse, mutect2, varscan2
- BIRC6 | c.13264G>A p.E4422K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as COSV70194968; called by muse, mutect2, varscan2
- BLM | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs971200482, COSV61921359; called by muse, mutect2, varscan2
- BMP15 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV53139763; called by muse, mutect2, varscan2
- BMP3 | c.1161G>C p.W387C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51087217, COSV51094819; called by muse, mutect2
- BMPR1B | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52774378; called by muse, mutect2, varscan2
- BMX | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 35/165 reads (21%) | catalogued as COSV59590048; called by muse, mutect2, varscan2
- BOC | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 20/145 reads (14%) | catalogued as COSV56346583; called by muse, mutect2, varscan2
- BOC | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); catalogued as COSV56346606; called by muse, mutect2, varscan2
- BOD1L1 | c.9023G>C p.R3008T | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1289595890, COSV50006293, COSV99238189; called by muse, mutect2, varscan2
- BOK | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs148098112, COSV59192007; called by muse, mutect2, varscan2
- BORCS6 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV66504723; called by muse, mutect2, varscan2
- BPTF | c.6572G>C p.R2191T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58830586; called by muse, mutect2, varscan2
- BRAF | c.1465G>A p.D489N (on ENST00000288602 / NM_001374244.1; = p.D449N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.979); catalogued as COSV56058533, COSV56201486; called by muse, mutect2, varscan2
- BRCA2 | c.2059G>C p.D687H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as COSV66447520; called by muse, mutect2, varscan2
- BRCA2 | c.3097G>C p.D1033H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780279081, COSV66447528, COSV66448865, COSV66462040; called by mutect2, varscan2
- BRD3 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs745362189, COSV57701196; called by muse, mutect2, varscan2
- BRD7 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67158185; called by muse, mutect2, varscan2
- BRD8 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs764808196, COSV50145017; called by muse, mutect2, varscan2
- BRINP3 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66511641, COSV66523421; called by muse, mutect2, varscan2
- BRPF1 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100121253; called by muse, mutect2
- BRWD1 | c.3436G>C p.E1146Q | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); catalogued as COSV60892318; called by muse, mutect2, varscan2
- BRWD3 | c.1151G>C p.R384P | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774748578, COSV104428237, COSV64743397; called by muse, mutect2, varscan2
- BSCL2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV54014615; called by muse, varscan2
- BSN | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV56516560; called by muse, mutect2
- BSN | c.6657G>T p.M2219I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV56512399; called by muse, mutect2, varscan2
- BSN | c.7570G>A p.E2524K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV56512412; called by muse, mutect2
- BSN | c.9568G>C p.E3190Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV99608405; called by muse, mutect2
- BSN | c.9857G>A p.R3286K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV99608407; called by muse, mutect2
- BTBD7 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs146101449, COSV58289000; called by muse, mutect2, varscan2
- BTN2A2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV61856487; called by muse, mutect2, varscan2
- BTN2A2 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61856495; called by muse, mutect2, varscan2
- BUB3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV64363464; called by muse, mutect2, varscan2
- BUD23 | c.261G>C p.M87I | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV56094081; called by muse, mutect2, varscan2
- BUD31 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV52860387, COSV52861879; called by muse, mutect2, varscan2
- C10orf88 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64403557; called by muse, mutect2, varscan2
- C10orf88 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV64403562, COSV64403801; called by muse, mutect2, varscan2
- C12orf4 | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV54205436; called by muse, mutect2, varscan2
- C14orf93 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100136703; called by muse, mutect2, varscan2
- C15orf40 | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58449168, COSV58450576; called by muse, mutect2, varscan2
- C16orf89 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV60121902; called by muse, mutect2, varscan2
- C17orf49 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66080710; called by muse, mutect2, varscan2
- C17orf64 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52255565; called by muse, mutect2, varscan2
- C17orf67 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 35/415 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV101190965; called by muse, mutect2
- C17orf67 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101190966; called by muse, mutect2
- C17orf80 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as COSV52144717; called by muse, mutect2, varscan2
- C19orf47 | c.1204G>C p.G402R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100775076; called by muse, mutect2
- C1GALT1C1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 75/143 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV100485614; called by muse, varscan2
- C1QTNF3 | c.84+3G>A | Splice Region (SNP) | VAF 30/94 reads (32%) | catalogued as COSV51467551; called by muse, varscan2
- C1orf116 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63943685; called by muse, mutect2, varscan2
- C1orf127 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV100983518, COSV65436208; called by muse, mutect2, varscan2
- C1orf87 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV64595913, COSV64595919; called by muse, mutect2, varscan2
- C21orf58 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs377051341; called by muse, mutect2, varscan2
- C2orf16 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV68645253; called by mutect2, varscan2
- C2orf16 | c.5025G>C p.Q1675H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV100820794, COSV62675442; called by muse, mutect2
- C2orf16 | c.5790G>C p.E1930D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.094); catalogued as COSV62673314; called by muse, mutect2, varscan2
- C2orf42 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as COSV52448670; called by muse, mutect2, varscan2
- C2orf49 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51527050; called by muse, mutect2, varscan2
- C3 | c.3803C>G p.S1268C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375151718, COSV55567922; called by muse, mutect2, varscan2
- C3 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV55567931; called by muse, mutect2, varscan2
- C3orf33 | c.262G>C p.E88Q (on ENST00000340171 / NM_001308229.2; = p.E45Q on NM_173657.2) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV60896199; called by muse, mutect2, varscan2
- C4B | c.3448C>T p.H1150Y | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV70313236; called by muse, mutect2, varscan2
- C6 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 41/175 reads (23%) | catalogued as rs374835229; called by muse, mutect2, varscan2
- C6orf89 | c.145C>T p.Q49* (on ENST00000373685; = p.Q56* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV62100867; called by muse, mutect2, varscan2
- C7orf26 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.442); catalogued as COSV60417814; called by muse, varscan2
- C8B | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV64776378, COSV64777362; called by muse, mutect2, varscan2
- C9orf131 | c.2278G>C p.E760Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as COSV56609429; called by muse, mutect2, varscan2
- C9orf50 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs547056212, COSV65252103; called by muse, mutect2, varscan2
- C9orf72 | c.1118G>C p.R373T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV66163264; called by muse, mutect2, varscan2
- C9orf85 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV58253119; called by muse, mutect2, varscan2
- CA12 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV51603953; called by muse, mutect2, varscan2
- CABIN1 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV54076959; called by muse, mutect2, varscan2
- CACNA1D | c.4270G>A p.E1424K (on ENST00000350061 / NM_001128840.3; = p.E1444K on NM_000720.4) | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as COSV55436105; called by muse, mutect2, varscan2
- CACNA1E | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV62381010; called by muse, mutect2, varscan2
- CACNA1E | c.5064G>T p.Q1688H | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV62381023; called by muse, mutect2, varscan2
- CACNA1E | c.6928G>C p.D2310H (on ENST00000367573 / NM_001205293.3; = p.D2267H on NM_000721.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62381035; called by muse, mutect2, varscan2
- CACNA1F | c.1865C>A p.S622* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV59902794; called by muse, mutect2, varscan2
- CACNA1G | c.4793C>T p.S1598F | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100661772; called by muse, mutect2
- CACNA1G | c.6247C>T p.H2083Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV100661775; called by muse, mutect2
- CACNA1G | c.7027C>T p.P2343S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV100661781; called by muse, mutect2
- CACNA1S | c.1730G>C p.G577A | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62935588; called by muse, mutect2, varscan2
- CACNA2D3 | c.292A>T p.M98L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV55510061; called by muse, mutect2, varscan2
- CACNB4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52387997; called by muse, mutect2, varscan2
- CAD | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53023131; called by muse, mutect2, varscan2
- CAD | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53023138; called by muse, varscan2
- CADPS | c.3309G>C p.M1103I | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV51865559; called by muse, mutect2, varscan2
- CADPS2 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV100462710; called by muse, mutect2, varscan2
- CALD1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs1354654711, COSV62644716; called by muse, mutect2, varscan2
- CAMK2A | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV62244832; called by muse, mutect2, varscan2
- CAMKK2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61212503; called by muse, mutect2, varscan2
- CAMKMT | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV65923147, COSV65929785; called by muse, mutect2, varscan2
- CAMSAP1 | c.2417C>A p.S806Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV56717883; called by muse, mutect2, varscan2
- CAMSAP1 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV56717907; called by muse, mutect2, varscan2
- CAMSAP2 | c.2539G>A p.D847N (on ENST00000236925 / NM_001297707.2; = p.D836N on NM_203459.3) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV52666376, COSV99374238; called by muse, mutect2, varscan2
- CAMSAP2 | c.2722G>C p.E908Q (on ENST00000236925 / NM_001297707.2; = p.E897Q on NM_203459.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV52666385; called by muse, mutect2, varscan2
- CAMTA2 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1265717136, COSV61832630; called by muse, mutect2, varscan2
- CAND1 | c.486G>C p.L162F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV73338526; called by muse, mutect2, varscan2
- CAPRIN2 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV51829937; called by muse, mutect2, varscan2
- CAPS2 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); catalogued as COSV60823832; called by muse, mutect2, varscan2
- CAPZB | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as COSV51644093; called by muse, mutect2, varscan2
- CARF | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57546044; called by muse, mutect2, varscan2
- CARMIL1 | c.3439G>T p.D1147Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV61513171; called by muse, mutect2, varscan2
- CARMIL2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as COSV58022569; called by muse, mutect2, varscan2
- CARS1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV53449504; called by muse, mutect2, varscan2
- CASC3 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV52865810; called by muse, mutect2, varscan2
- CASP10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV53776439, COSV53779511; called by muse, mutect2
- CASP8AP2 | c.2392A>C p.S798R | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV52744966; called by muse, mutect2, varscan2
- CASP8AP2 | c.2890C>T p.R964W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs781619316, COSV52744977; called by muse, mutect2, varscan2
- CASR | c.1124G>C p.R375T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV99948951; called by muse, mutect2, varscan2
- CASS4 | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV64385294; called by muse, mutect2, varscan2
- CASS4 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64385299; called by muse, mutect2, varscan2
- CATIP | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV56821712; called by muse, mutect2, varscan2
- CATSPER4 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV58792098; called by muse, mutect2, varscan2
- CATSPERE | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63675557; called by muse, mutect2, varscan2
- CAV1 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV61952427; called by muse, mutect2, varscan2
- CBX4 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as COSV99490347; called by muse, mutect2
- CC2D1B | c.1107del p.D370Tfs*23 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as COSV52558098; called by mutect2, varscan2
- CC2D2A | c.2740C>T p.L914F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67501986; called by muse, mutect2, varscan2
- CCDC106 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99553123; called by muse, varscan2
- CCDC116 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.089); catalogued as COSV53039162, COSV99489334; called by muse, mutect2, varscan2
- CCDC15 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as COSV61080031; called by muse, mutect2, varscan2
- CCDC150 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV55871023; called by muse, mutect2, varscan2
- CCDC150 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV55871031; called by muse, mutect2, varscan2
- CCDC150 | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55871043; called by muse, mutect2, varscan2
- CCDC153 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV59538592; called by muse, mutect2, varscan2
- CCDC173 | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV71428550; called by muse, mutect2, varscan2
- CCDC178 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV55756949; called by muse, mutect2, varscan2
- CCDC180 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV63826310; called by muse, mutect2, varscan2
- CCDC191 | c.2619G>C p.W873C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.719); catalogued as COSV55669788; called by muse, mutect2, varscan2
- CCDC30 | c.2113G>A p.E705K (on ENST00000340612; = p.E662K on NM_001080850.3) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV59604079; called by muse, mutect2, varscan2
- CCDC34 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV60820007; called by muse, mutect2, varscan2
- CCDC38 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV60182055; called by muse, mutect2, varscan2
- CCDC40 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.003); catalogued as rs746951379, COSV53896134; called by muse, mutect2, varscan2
- CCDC78 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV52400474; called by muse, mutect2, varscan2
- CCDC88A | c.5203G>C p.V1735L (on ENST00000436346 / NM_001365480.1; = p.V1707L on NM_018084.5) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55055614; called by muse, mutect2, varscan2
- CCDC88A | c.4200G>A p.M1400I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55055638; called by muse, mutect2, varscan2
- CCDC88A | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV55055658; called by muse, mutect2, varscan2
- CCDC88A | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV55055678; called by muse, mutect2, varscan2
- CCIN | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs1423162702, COSV58723905; called by muse, mutect2, varscan2
- CCN6 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as CD126428, COSV57888422; called by muse, mutect2, varscan2
- CCNB1 | c.22-1G>A p.X8_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as COSV56509018; called by muse, mutect2, varscan2
- CCNL2 | c.902del p.R301Kfs*52 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as COSV68766062; called by mutect2, pindel, varscan2
- CCNT2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV51470837; called by muse, mutect2, varscan2
- CCNT2 | c.2140G>C p.D714H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV51470853; called by muse, mutect2, varscan2
- CCNYL1 | c.253C>T p.P85S (on ENST00000295414 / NM_001330218.2; = p.P15S on NM_152523.2) | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54938827; called by muse, varscan2
- CCNYL1 | c.286C>G p.Q96E (on ENST00000295414 / NM_001330218.2; = p.Q26E on NM_152523.2) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV54938842; called by muse, varscan2
- CCPG1 | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV60523872; called by muse, mutect2, varscan2
- CCR6 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV100551074; called by muse, varscan2
- CCRL2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.182); catalogued as COSV62193148; called by muse, mutect2, varscan2
- CCSER2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56500835; called by muse, mutect2, varscan2
- CCSER2 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56500858; called by muse, mutect2, varscan2
- CCT2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54738945, COSV54740081; called by muse, mutect2, varscan2
- CCT8 | c.1097-1G>C p.X366_splice | Splice Site (SNP) | VAF 38/155 reads (25%) | catalogued as COSV54502730; called by muse, mutect2, varscan2
- CD101 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56715694; called by muse, mutect2, varscan2
- CD109 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs745425108, COSV54644487; called by muse, mutect2, varscan2
- CD109 | c.2918C>G p.S973C | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54644503; called by muse, mutect2, varscan2
- CD109 | c.3850G>C p.D1284H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV54644530; called by muse, mutect2, varscan2
- CD163L1 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs918375123, COSV58010384, COSV58019196; called by muse, mutect2, varscan2
- CD163L1 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100550480, COSV58010390; called by muse, mutect2, varscan2
- CD1A | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56860126; called by muse, mutect2, varscan2
- CD200R1 | c.352C>G p.Q118E (on ENST00000471858 / NM_170780.3; = p.Q141E on NM_138806.4) | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV99867208; called by muse, mutect2
- CD248 | c.1870C>G p.Q624E | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1355315783, COSV60935648, COSV60938185; called by muse, mutect2, varscan2
- CD300A | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV60409388; called by muse, mutect2, varscan2
- CD300E | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100151288; called by muse, mutect2, varscan2
- CD300LD | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV60083259; called by muse, mutect2, varscan2
- CD33 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV51799700; called by muse, mutect2, varscan2
- CD36 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs750187438, COSV59209379; called by muse, mutect2, varscan2
- CD47 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62526472, COSV62528602; called by muse, mutect2, varscan2
- CD53 | c.324G>C p.Q108H | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs779244088, COSV54759746; called by muse, mutect2, varscan2
- CD5L | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as COSV63820962; called by muse, mutect2, varscan2
- CD63 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs11574657; called by muse, mutect2, varscan2
- CD68 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs771826335, COSV51509677; called by muse, mutect2, varscan2
- CD70 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55565444; called by muse, mutect2, varscan2
- CD72 | c.1016C>G p.S339* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV52409758, COSV52412360; called by mutect2, varscan2
- CD8A | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.229); catalogued as COSV52156384, COSV52158909; called by muse, mutect2, varscan2
- CDC27 | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99294834; called by muse, varscan2
- CDC37 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779190160, COSV55767086, COSV55767669; called by muse, mutect2, varscan2
- CDC5L | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV65175107, COSV65177679; called by muse, mutect2, varscan2
- CDH12 | c.996G>C p.L332F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66385888; called by muse, mutect2, varscan2
- CDH16 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55334552, COSV55337783; called by muse, mutect2, varscan2
- CDH2 | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV52270085; called by muse, mutect2, varscan2
- CDH20 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV53003755, COSV53008290, COSV99406679; called by muse, mutect2, varscan2
- CDH23 | c.3388G>A p.D1130N | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs1374962047, CM140474, COSV56445840; called by muse, mutect2, varscan2
- CDH24 | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV52972619; called by muse, mutect2, varscan2
- CDH26 | c.2027C>G p.S676* (on ENST00000348616 / NM_177980.4; = p.S9* on NM_021810.6) | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | catalogued as COSV54842129; called by muse, mutect2, varscan2
- CDH9 | c.1660del p.D554Mfs*8 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as COSV50250781; called by mutect2, pindel, varscan2
- CDH9 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV50250791, COSV50330041; called by muse, mutect2, varscan2
- CDHR1 | c.526-1G>A p.X176_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as COSV60559220; called by muse, mutect2, varscan2
- CDHR3 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58413236; called by muse, mutect2, varscan2
- CDK12 | c.3436A>C p.M1146L | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101420446; called by muse, mutect2
- CDK12 | c.4136C>G p.S1379C (on ENST00000447079 / NM_016507.4; = p.S1370C on NM_015083.3) | Missense Mutation (SNP) | VAF 27/340 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs778399102, COSV70999077; called by muse, mutect2
- CDK13 | c.1738C>G p.L580V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1002791528, COSV51695856; called by muse, mutect2, varscan2
- CDK13 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51695866; called by muse, mutect2, varscan2
- CDK17 | c.154C>G p.H52D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as COSV54126243; called by muse, mutect2, varscan2
- CDK3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs1424386342, COSV56906683; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1930C>T p.Q644* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV62571716; called by muse, mutect2, varscan2
- CDKL5 | c.3025C>T p.H1009Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV66105773; called by muse, mutect2, varscan2
- CDON | c.3310G>C p.D1104H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54994674; called by muse, mutect2, varscan2
- CDRT15 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV101415149; called by muse, mutect2
- CEACAM3 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV55760630, COSV99705140; called by muse, mutect2, varscan2
- CELA2A | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62747160, COSV62747887; called by muse, mutect2, varscan2
- CELF3 | c.1152C>G p.I384M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51881267; called by muse, mutect2, varscan2
- CELF4 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV58445358; called by muse, mutect2, varscan2
- CELSR2 | c.4428G>C p.E1476D | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV54766060, COSV99603258; called by muse, mutect2, varscan2
- CEND1 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV57192145; called by muse, mutect2, varscan2
- CENPC | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99893904; called by muse, mutect2, varscan2
- CENPE | c.4947G>C p.L1649F | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as COSV54375457; called by muse, mutect2, varscan2
- CENPE | c.3721C>T p.H1241Y | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs1243982629, COSV54375473; called by muse, mutect2, varscan2
- CENPF | c.3035C>T p.S1012L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as COSV65272336; called by muse, mutect2, varscan2
- CENPL | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.081); catalogued as COSV61891369; called by muse, mutect2, varscan2
- CENPO | c.325C>G p.H109D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV53163844; called by muse, mutect2, varscan2
- CEP120 | c.1370C>G p.S457* | Nonsense Mutation (SNP) | VAF 51/97 reads (53%) | catalogued as COSV60263701; called by muse, mutect2, varscan2
- CEP135 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV57257805; called by muse, mutect2, varscan2
- CEP152 | c.3285G>T p.Q1095H | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV57856229; called by muse, mutect2, varscan2
- CEP152 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.287); catalogued as COSV57856248; called by muse, mutect2, varscan2
- CEP164 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54037780; called by muse, mutect2, varscan2
- CEP170 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60505487; called by muse, mutect2, varscan2
- CEP19 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.562); catalogued as COSV56358892; called by muse, mutect2, varscan2
- CEP250 | c.4303G>C p.E1435Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV61167893; called by muse, mutect2, varscan2
- CEP290 | c.4490C>G p.S1497* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as COSV58348105; called by muse, mutect2, varscan2
- CEP63 | c.1735C>A p.H579N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV59674164; called by muse, mutect2, varscan2
- CEP68 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV53123196; called by muse, mutect2, varscan2
- CEP78 | c.1609C>T p.L537F (on ENST00000424347 / NM_001349840.2; = p.L538F on NM_032171.3) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52845236; called by muse, mutect2, varscan2
- CEP83 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60406337; called by muse, mutect2, varscan2
- CEP85 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV53326494; called by muse, mutect2, varscan2
- CEP85L | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441929344, COSV63820500; called by muse, mutect2, varscan2
- CEP95 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.172); catalogued as COSV73608520; called by muse, mutect2, varscan2
- CEP97 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.215); catalogued as COSV59122377; called by muse, mutect2, varscan2
- CER1 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV66602847; called by muse, mutect2, varscan2
- CERK | c.1539C>T p.V513= | Splice Region (SNP) | VAF 12/27 reads (44%) | catalogued as COSV53449931; called by muse, mutect2, varscan2
- CERS2 | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV99644603; called by muse, mutect2, varscan2
- CERS5 | c.1017G>T p.L339F | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as COSV58188152; called by muse, mutect2, varscan2
- CETP | c.438G>C p.L146= | Splice Region (SNP) | VAF 40/128 reads (31%) | catalogued as COSV52361223, COSV99570121; called by muse, mutect2, varscan2
- CFAP20 | c.468C>T p.I156= | Splice Region (SNP) | VAF 15/55 reads (27%) | catalogued as COSV52630393; called by muse, mutect2, varscan2
- CFAP20DC | c.1546G>C p.D516H (on ENST00000482387 / NM_001351530.2; = p.D391H on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV55915397; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.513); catalogued as COSV55828272; called by muse, mutect2, varscan2
- CFAP36 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV59116449; called by muse, mutect2, varscan2
- CFAP46 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV63948946; called by muse, mutect2, varscan2
- CFAP47 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52880055; called by muse, mutect2, varscan2
- CFAP58 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs1297491277, COSV63832378; called by muse, mutect2, varscan2
- CFAP69 | c.502C>G p.H168D | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.51); catalogued as COSV60183957; called by muse, mutect2, varscan2
- CFAP91 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1207533384, COSV56338737; called by muse, mutect2, varscan2
- CFAP92 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV54045760; called by muse, mutect2, varscan2
- CFAP94 | c.824C>T p.S275F (on ENST00000320267 / NM_001352064.2; = p.S281F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV57229658; called by muse, mutect2, varscan2
- CFDP1 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52207232; called by muse, mutect2, varscan2
- CFDP1 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs377603272; called by muse, mutect2, varscan2
- CFHR5 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56817511, COSV56818106; called by muse, mutect2, varscan2
- CFTR | c.3568G>C p.V1190L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as COSV50040481; called by muse, mutect2, varscan2
- CGN | c.3427G>C p.E1143Q | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54967683; called by muse, mutect2, varscan2
- CGNL1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV55562846; called by muse, mutect2, varscan2
- CHAMP1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV63521619; called by muse, mutect2, varscan2
- CHAT | c.999G>C p.L333F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV60319406, COSV60332083; called by muse, mutect2, varscan2
- CHCHD2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs769442639, COSV68169791; called by muse, mutect2, varscan2
- CHD1L | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as COSV63612559; called by muse, mutect2, varscan2
- CHD2 | c.5329C>G p.L1777V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs769085842, COSV67706437; called by muse, mutect2, varscan2
- CHD3 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV57872111; called by muse, mutect2, varscan2
- CHD4 | c.3928G>C p.E1310Q (on ENST00000357008 / NM_001363606.2; = p.E1323Q on NM_001273.5) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58893732; called by muse, mutect2, varscan2
- CHD5 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1321915524, COSV52406775; called by muse, mutect2, varscan2
- CHD6 | c.1159A>G p.K387E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV58553344; called by muse, mutect2, varscan2
- CHD7 | c.6529G>A p.E2177K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs750047137, COSV71106800; called by mutect2, varscan2
- CHD8 | c.3095G>C p.R1032T (on ENST00000646647 / NM_001170629.2; = p.R753T on NM_020920.4) | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67869495; called by muse, mutect2, varscan2
- CHD9 | c.7360C>T p.H2454Y (on ENST00000398510 / NM_001382353.1; = p.H2438Y on NM_025134.7) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54607065; called by muse, mutect2, varscan2
- CHEK1 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 126/246 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV54021902; called by muse, mutect2, varscan2
- CHEK2 | c.1315C>G p.L439V (on ENST00000382580 / NM_001005735.2; = p.L396V on NM_007194.4) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs886041172, COSV60415131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHGB | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV66759468; called by muse, mutect2, varscan2
- CHM | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD137313, COSV63299964; called by muse, mutect2, varscan2
- CHORDC1 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV57705079; called by muse, mutect2, varscan2
- CHPT1 | c.677T>G p.I226S | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV57532610; called by muse, mutect2, varscan2
- CHRM1 | c.1080G>C p.E360D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV61006045; called by muse, mutect2, varscan2
- CHRNA3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV58773865; called by muse, mutect2, varscan2
- CHRNA5 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV55137240; called by muse, mutect2, varscan2
- CHRNE | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV99544938; called by muse, mutect2, varscan2
- CHST11 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100359423, COSV100359926; called by muse, mutect2
- CHSY1 | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141063, COSV54251139, COSV54254124; called by mutect2, varscan2
- CIAO1 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51496809; called by muse, mutect2, varscan2
- CIC | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.378); catalogued as COSV50546546, COSV50673060; called by muse, mutect2, varscan2
- CILK1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV63153258; called by muse, mutect2, varscan2
- CIP2A | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as COSV55416865; called by muse, mutect2, varscan2
- CIT | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs747447396, COSV55868757; called by muse, mutect2, varscan2
- CKAP4 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as COSV65172084; called by muse, mutect2, varscan2
- CLASP1 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV55312103; called by muse, mutect2, varscan2
- CLCA2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV65285823; called by muse, mutect2, varscan2
- CLCA2 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65285830; called by muse, mutect2, varscan2
- CLCN2 | c.2321G>A p.W774* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | catalogued as COSV55598995; called by muse, mutect2, varscan2
- CLCN7 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51968063; called by mutect2, varscan2
- CLCNKA | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58890202; called by mutect2, varscan2
- CLEC2D | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV51992369; called by muse, mutect2, varscan2
- CLEC6A | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV65986612; called by muse, mutect2, varscan2
- CLIP1 | c.4171G>C p.E1391Q (on ENST00000620786 / NM_001247997.1; = p.E1380Q on NM_002956.2) | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1251120121, COSV56796656; called by muse, mutect2, varscan2
- CLIP1 | c.3763G>A p.E1255K (on ENST00000620786 / NM_001247997.1; = p.E1244K on NM_002956.2) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100212059, COSV56796675; called by muse, mutect2, varscan2
- CLIP1 | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV56796697; called by muse, mutect2, varscan2
- CLIP1 | c.140C>G p.S47* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV56796715, COSV56806329; called by muse, mutect2, varscan2
- CLK3 | c.516G>T p.R172S (on ENST00000395066 / NM_001130028.1; = p.R24S on NM_003992.4) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV61411575; called by muse, mutect2, varscan2
- CLK4 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 25/118 reads (21%) | catalogued as COSV60317510; called by muse, mutect2, varscan2
- CLRN1 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV58992457, COSV58995663; called by muse, mutect2, varscan2
- CLSPN | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52046093; called by muse, mutect2, varscan2
- CLTC | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 23/451 reads (5%) | catalogued as COSV99292250; called by muse, mutect2
- CLTC | c.4114G>C p.D1372H | Missense Mutation (SNP) | VAF 24/453 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99292255; called by muse, mutect2
- CLUH | c.1260C>G p.I420M (on ENST00000435359; = p.I458M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV70927530; called by muse, mutect2, varscan2
- CMTR2 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs755193044, COSV57602399; called by muse, mutect2, varscan2
- CMYA5 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV71404014; called by muse, mutect2, varscan2
- CMYA5 | c.3953C>G p.S1318* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV71404015; called by mutect2, varscan2
- CMYA5 | c.5525C>G p.S1842C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV71404016; called by muse, mutect2, varscan2
- CMYA5 | c.7890G>C p.E2630D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV71404017; called by muse, mutect2, varscan2
- CNGB1 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51897035; called by muse, mutect2, varscan2
- CNGB3 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769850965, COSV60683898; called by muse, mutect2, varscan2
- CNKSR2 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV54248710; called by muse, mutect2, varscan2
- CNKSR2 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV54248725; called by muse, mutect2, varscan2
- CNKSR2 | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV65278631; called by muse, mutect2, varscan2
- CNN1 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV52947322; called by muse, mutect2, varscan2
- CNOT10 | c.1156C>G p.H386D | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV59389841; called by muse, mutect2, varscan2
- CNOT11 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as COSV56818850; called by muse, mutect2, varscan2
- CNOT2 | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV57500106; called by muse, mutect2, varscan2
- CNOT2 | c.1620C>G p.F540L | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV57500117; called by mutect2, varscan2
- CNOT6 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.148); catalogued as COSV56159092, COSV56161394; called by muse, mutect2, varscan2
- CNOT6 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV56159106; called by muse, mutect2, varscan2
- CNOT9 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55298808; called by muse, mutect2, varscan2
- CNPY2 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV56263773; called by muse, mutect2, varscan2
- CNST | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV63621417; called by muse, mutect2, varscan2
- CNTN1 | c.2882C>T p.S961F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV61635632; called by muse, mutect2, varscan2
- CNTN3 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV55161917, COSV99726007; called by muse, mutect2, varscan2
- CNTN6 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63160336; called by muse, mutect2, varscan2
- CNTNAP2 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs750079255, COSV62140550; called by muse, mutect2, varscan2
- CNTNAP5 | c.1704C>G p.F568L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV70470067; called by muse, varscan2
- CNTNAP5 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV70470072; called by muse, mutect2, varscan2
- CNTRL | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs776657382, COSV53042579; called by muse, mutect2, varscan2
- CNTRL | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53042589; called by muse, mutect2, varscan2
- CNTRL | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53042600; called by muse, mutect2, varscan2
- CNTROB | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.221); catalogued as rs749213618, COSV66607373; called by muse, mutect2, varscan2
- COA6 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64016677; called by muse, mutect2, varscan2
- COG5 | c.2287G>C p.E763Q (on ENST00000347053 / NM_001379512.1; = p.E784Q on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV51741781; called by muse, mutect2, varscan2
- COIL | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 27/414 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV99538167; called by muse, mutect2
- COL11A1 | c.3863G>C p.G1288A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62171384; called by muse, mutect2, varscan2
- COL11A1 | c.2288G>C p.G763A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62171396; called by muse, mutect2, varscan2
- COL12A1 | c.7281G>T p.K2427N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59388555; called by muse, mutect2, varscan2
- COL12A1 | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV59388599; called by muse, mutect2, varscan2
- COL14A1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV52846300; called by muse, mutect2, varscan2
- COL14A1 | c.1165C>G p.P389A | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.545); catalogued as COSV52848687, COSV99919249; called by muse, mutect2, varscan2
- COL14A1 | c.4733G>C p.G1578A | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV52846308, COSV99918834, COSV99920412; called by muse, mutect2, varscan2
- COL18A1 | c.1509C>G p.F503L (on ENST00000359759 / NM_130444.3; = p.F268L on NM_030582.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV62698158, COSV62706873; called by muse, mutect2, varscan2
- COL1A1 | c.2818G>A p.D940N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs779431392, COSV56802096; called by muse, varscan2
- COL27A1 | c.2315G>C p.G772A | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61921017; called by muse, mutect2, varscan2
- COL2A1 | c.3299C>A p.S1100* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV61527459; called by muse, mutect2, varscan2
- COL3A1 | c.3924G>C p.L1308F | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV58581187; called by muse, mutect2, varscan2
- COL4A1 | c.3220T>A p.F1074I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV65420538; called by muse, mutect2, varscan2
- COL4A2 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV64624286; called by muse, mutect2, varscan2
- COL4A5 | c.3914C>T p.P1305L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs757706609, COSV60355502; called by muse, mutect2, varscan2
- COL4A5 | c.4829C>T p.S1610L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750941179, COSV100087681; called by muse, mutect2, varscan2
- COL5A1 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100879833, COSV65664515; called by muse, mutect2, varscan2
- COL5A3 | c.1217C>G p.S406* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV53409186, COSV99318981; called by muse, mutect2
- COL6A6 | c.3589C>G p.Q1197E | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100650247; called by muse, mutect2
- COL7A1 | c.3703C>T p.Q1235* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs1354674050, COSV60390598; called by muse, mutect2, varscan2
- COL9A1 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as COSV61827884, COSV61837684; called by muse, mutect2, varscan2
- COMMD1 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV61273397; called by muse, mutect2, varscan2
- COMMD10 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as COSV57233455; called by muse, mutect2, varscan2
- COMMD9 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54671490; called by muse, mutect2, varscan2
- COP1 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs753910989, COSV58162390, COSV58179829; called by muse, mutect2, varscan2
- COPB2 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 25/202 reads (12%) | catalogued as COSV60811693; called by muse, mutect2, varscan2
- COPG2 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV58404064; called by muse, mutect2, varscan2
- COPS9 | c.137-1G>C p.X46_splice (on ENST00000607357 / NM_001163424.2; = p.X77_splice on NM_138336.1) | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV56227690; called by muse, mutect2, varscan2
- COPZ2 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV50058421, COSV99133599; called by muse, mutect2
- CORO1C | c.1372C>G p.Q458E | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV54593802; called by muse, mutect2, varscan2
- COTL1 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.408); catalogued as COSV52289241; called by muse, mutect2, varscan2
- CPA2 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 59/179 reads (33%) | catalogued as COSV55978526; called by muse, mutect2, varscan2
- CPB1 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV51571039; called by muse, mutect2, varscan2
- CPB1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51571054; called by muse, mutect2, varscan2
- CPD | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV56710351; called by muse, varscan2
- CPD | c.1927C>G p.Q643E | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs375764127, COSV99075767; called by muse, mutect2, varscan2
- CPD | c.3152C>G p.S1051* | Nonsense Mutation (SNP) | VAF 41/175 reads (23%) | catalogued as COSV56710361; called by muse, mutect2, varscan2
- CPD | c.3388C>A p.H1130N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99852847; called by muse, mutect2, varscan2
- CPEB1 | c.1510G>A p.E504K (on ENST00000617958; = p.E439K on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55616935, COSV55617303; called by muse, mutect2, varscan2
- CPLANE1 | c.9242C>G p.S3081C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV57050718; called by muse, mutect2, varscan2
- CPN2 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV60469452; called by muse, varscan2
- CPN2 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as COSV60469457; called by muse, varscan2
- CPNE5 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs145606112; called by muse, mutect2, varscan2
- CPS1 | c.622-1G>A p.X208_splice | Splice Site (SNP) | VAF 19/91 reads (21%) | catalogued as COSV51800618; called by muse, mutect2, varscan2
- CPS1 | c.3148G>A p.G1050S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV51800640; called by muse, mutect2, varscan2
- CPSF1 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV58231934; called by muse, mutect2, varscan2
- CPXM2 | c.1512G>C p.W504C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99582189; called by muse, mutect2
- CRAMP1 | c.894G>C p.K298N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51959166; called by muse, mutect2, varscan2
- CRAMP1 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV51959383; called by muse, mutect2, varscan2
- CRAT | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as COSV58875729; called by muse, mutect2, varscan2
- CROCC | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV65009634; called by muse, mutect2, varscan2
- CRP | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV54812466, COSV54812533; called by muse, mutect2, varscan2
- CRTAC1 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.067); catalogued as COSV53996322; called by muse, mutect2, varscan2
- CRTAM | c.960G>C p.K320N | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57066227; called by muse, mutect2, varscan2
- CRYGB | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs761343235, COSV53679614; called by muse, mutect2, varscan2
- CSF1R | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV53827575; called by muse, mutect2, varscan2
- CSMD2 | c.4176G>C p.Q1392H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV53874596; called by muse, mutect2, varscan2
- CSMD2 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53874654; called by muse, mutect2, varscan2
- CSNK1A1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55792259, COSV55798180; called by muse, mutect2, varscan2
- CSPP1 | c.643C>A p.Q215K (on ENST00000676605; = p.Q174K on NM_024790.6) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV51579567; called by muse, mutect2, varscan2
- CSPP1 | c.1373G>C p.G458A (on ENST00000676605; = p.G417A on NM_024790.6) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51579585; called by muse, mutect2, varscan2
- CSRP2 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV60702008; called by muse, mutect2, varscan2
- CSTF3 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV60609156; called by muse, mutect2, varscan2
- CTBP1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52071481, COSV52072948; called by muse, mutect2, varscan2
- CTC1 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.082); catalogued as COSV59851778; called by muse, mutect2, varscan2
- CTCFL | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54770144; called by muse, mutect2, varscan2
4,314 further variants in this file (3,060 protein-altering or splice-affecting, 1,159 silent, 95 other) are not listed here.
